CCDI case PBBXED — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/c414eb27-6957-47a3-9091-a488811eef2e

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Carcinoma, NOS: ICD-O-3 morphology code: 8010/3; Tissue or organ of origin: Nasal cavity; Age at diagnosis: 14.7 years (5,377 days).

Biospecimens (3 samples)
- Sample 0DJPCN: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DJPCT: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DJPD9: Tissue type: Tumor; Specimen type: Solid Tissue.
